Somatic mutation profile of tumor specimen 0DE0TW from CCDI case PBBPIV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 15.6 years (5,715 days).
Specimen 0DE0TW: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 57d96568-c7d3-4cd9-97dd-ac8b9a8b0329.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DE0QP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ed9fff4-74c4-4120-824a-3dc5110ce2fe

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 3, Nonsense Mutation 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC168 | c.19792C>T p.R6598* | Nonsense Mutation (SNP) | VAF 103/256 reads (40%) | catalogued as rs767450599; called by muse, mutect2, varscan2
- CSPG4 | c.3146C>T p.S1049L | Missense Mutation (SNP) | VAF 95/207 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs531178999, COSV100413910; called by muse, mutect2, varscan2
- MS4A14 | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 45/378 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV55737042; called by muse, mutect2, varscan2
- ADGRB3 | c.2683C>A p.L895I | Missense Mutation (SNP) | VAF 182/445 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAS1L | c.101G>A p.G34D | Missense Mutation (SNP) | VAF 100/253 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- MPDZ | c.1539A>C p.E513D | Missense Mutation (SNP) | VAF 60/330 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.255); called by muse, varscan2
- OR10J5 | c.10A>T p.K4* | Nonsense Mutation (SNP) | VAF 38/264 reads (14%) | called by muse, mutect2, varscan2
- XIRP1 | c.5197C>G p.P1733A | Missense Mutation (SNP) | VAF 35/487 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, mutect2
- BTBD6 | c.810A>C p.R270= | Silent (SNP) | VAF 36/272 reads (13%) | called by muse, mutect2, varscan2
- COL7A1 | c.6126C>T p.P2042= | Silent (SNP) | VAF 152/389 reads (39%) | catalogued as rs777837431, COSV60403049; called by muse, mutect2, varscan2
- HCLS1 | c.400-93T>A | Intron (SNP) | VAF 11/41 reads (27%) | called by muse, mutect2, varscan2
- KIF9 | c.981+54G>A | Intron (SNP) | VAF 107/257 reads (42%) | called by muse, mutect2, varscan2
- PHF8 | c.2237+68C>T | Intron (SNP) | VAF 203/229 reads (89%) | called by muse, mutect2, varscan2
